MMRF case MMRF_2599 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/61a625e1-1c07-449d-8827-fc18f04aea26

Demographics
Sex at birth: female; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.7 years (26,204 days); ISS stage: II; Days to last known disease status: 625 days (1.7 years); Days to last follow up: 625 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 114 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5: M Protein 4.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 65.5 mg/dL; Immunoglobulin G 67.4 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 3.9 µg/mL; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 11.2 g/dL; Glucose 4.4 mmol/L; C-Reactive Protein 0.276 mg/dL.
- Day 92 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 4.36 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 8.93 ×10⁹/L; Platelets 331 ×10⁹/L; Creatinine 41.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 5.6 g/dL; Glucose 7.04 mmol/L.
- Day 190 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 3.29 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 10.9 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 339 ×10⁹/L; Creatinine 30.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.08 mmol/L; Albumin 31 g/L; Total Protein 5.3 g/dL; Glucose 4.57 mmol/L.
- Day 281 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.38 mg/dL; Immunoglobulin G 8.93 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 253 ×10⁹/L; Creatinine 43.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 4.24 mmol/L.
- Day 372: M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 8.62 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 43.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 5.06 mmol/L.
- Day 457 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.99 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 4.68 mmol/L.
- Day 541 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.63 mg/dL; Immunoglobulin G 9.27 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 4.9 mmol/L.
- Day 625 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.3 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.8 g/dL; Glucose 4.79 mmol/L.

Other clinical attributes
- Day -5: Weight: 54 kg; Height: 160 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_2599_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2599_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
